Surgical pathology report (de-identified scan), TCGA case TCGA-XE-AANN, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-XE-AANN-01A (Primary Tumor).

[page 1 of 2]
Ord #=
SURGICAL PATHOL
Modifiers:

RESULTED

Collect D/T=

(1 of 1)

Surgical Pathology Report

Specimen(s) Received
Right testicle

Clinical History
Not stated

ICD-O-3
Seminoma NOS 9061/3
Site R Testis NOS C62.9
JY 3/31/14

Gross Description

Right testicle: Received fresh from the OR labeled with patient's name and medical record number is a 166-gram testicle that measures 8.5 x 7 x 6 cm. The spermatic cord measures 9.5 cm in length x 1 cm in average diameter and epididymis measures 1 x 1.1 x .6 cm. There is a 6 x 5.5 x 3.5 cm tan yellow firm circumscribed mass with slight lobulation. There are two areas of tan-yellow slightly hemorrhagic discoloration within the mass, one of which measures 1.2 x 1 x 0.2 cm. and the other which measures 2.7 x 1.1 x 0.4 cm. There are no obvious areas of necrosis or hemorrhage identified. The tumor does not grossly extend into the tunica albuginea or into the epididymis. The remainder of the testicular parenchyma is tan brown and appears unremarkable. The spermatic cord appears grossly unremarkable and uninvolved by tumor. The outer surface of the specimen is inked black. A section is taken for research. Representative sections of the specimen are submitted as follows:

- 1 Spermatic cord margin
- 2 Mid section spermatic cord
- 3 Peri testicular spermatic cord
- 4 Tumor and adjacent unremarkable testis
- 5 Tumor and possible epididymis
- 6 Tunica vaginalis
- 7-12 Tumor
- 12

Date of Dictation:

Gross Description By:

[page 2 of 2]
Acc#

(Continued)

Acct#:

Microscopic Description
Performed.

Final Pathologic Diagnosis

Specimen Type: Radical Orchiectomy

Laterality: Right

Focality:

Unifocal

Tumor Size: 6 cm.

Histologic Type: Seminoma.

Intratubular germ cell neoplasia is not identified.

Tumor does not involve rete testis, epididymis, spermatic cord, or tunica vaginalis.

Tumor extends into peri-hilar fat (slide A5)

Lymphovascular Invasion: Not identified.

Margin: Spermatic cord margin is negative for tumor.

Remaining testicular tissue shows atrophy.

Pathologic Tumor Stage: pT1NXMX (Stage I)

Attending Pathologist:

***Electronically Signed Out By

Patient Name:

Case #:

Med. Rec. #:

Location:

Date Collected:

Criteria:	hw 1/21/14	Yes	No

Source: NCI Genomic Data Commons file 8ae86ee3-5066-4ad9-8e14-d29efbd06847 (TCGA-XE-AANN-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).